Somatic mutation profile of tumor specimen 0DQOF7 from CCDI case PBCEPD, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Spindle cell sarcoma; Tissue or organ of origin: Lymph nodes of axilla or arm; Age at diagnosis: 18.6 years (6,798 days).
Specimen 0DQOF7: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2b1ab9d4-a5fb-41e2-a9e3-db911e38980e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DQOES (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/670b96ee-0e5a-4c5f-b579-319dddf6e1db

The open-access MAF lists 26 somatic variants for this specimen: 18 protein-altering or splice-affecting, 3 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 3, 5'UTR 2, Intron 2, 3'UTR 1, Nonsense Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.464C>A p.T155N | Missense Mutation (SNP) | VAF 392/671 reads (58%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.666); catalogued as rs786202752, CM942117, HM090066, COSV52692291, COSV52711720, COSV52741190, COSV52782333; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- CELF4 | c.936G>A p.M312I | Missense Mutation (SNP) | VAF 296/673 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs200680800, COSV58453429; called by muse, mutect2, varscan2
- DIDO1 | c.6664C>T p.R2222W | Missense Mutation (SNP) | VAF 125/637 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.948); catalogued as rs750404254; called by muse, mutect2, varscan2
- DNAH5 | c.7481C>T p.A2494V | Missense Mutation (SNP) | VAF 308/778 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1428862297, COSV99456591; called by muse, mutect2, varscan2
- SARAF | c.608C>T p.P203L | Missense Mutation (SNP) | VAF 328/986 reads (33%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.999); catalogued as rs561853962, COSV56357781; called by muse, mutect2, varscan2
- SRRM4 | c.551G>A p.R184H | Missense Mutation (SNP) | VAF 179/1070 reads (17%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.082); catalogued as rs777138675, COSV57411474; called by muse, mutect2, varscan2
- ACLY | c.1381G>C p.A461P | Missense Mutation (SNP) | VAF 71/830 reads (9%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2
- AKNA | c.1345G>T p.D449Y | Missense Mutation (SNP) | VAF 71/623 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ALDH5A1 | c.854C>A p.S285* | Nonsense Mutation (SNP) | VAF 44/1276 reads (3%) | called by muse, mutect2
- FRAS1 | c.5485G>A p.A1829T | Missense Mutation (SNP) | VAF 493/1290 reads (38%) | SIFT tolerated (0.26); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- GOLGA6L2 | c.957G>C p.Q319H | Missense Mutation (SNP) | VAF 62/412 reads (15%) | SIFT deleterious, low confidence (0.01); called by muse, mutect2, varscan2
- NDC1 | c.1739G>C p.R580T | Missense Mutation (SNP) | VAF 277/1518 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- NF1 | c.4295del p.P1432Hfs*8 (on ENST00000358273 / NM_001042492.3; = p.P1411Hfs*8 on NM_000267.3) | Frame Shift Del (DEL) | VAF 521/1013 reads (51%) | called by mutect2, pindel, varscan2
- STXBP2 | c.385A>G p.T129A | Missense Mutation (SNP) | VAF 130/767 reads (17%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.768); called by muse, mutect2, varscan2
- SUZ12 | c.719G>C p.S240T | Missense Mutation (SNP) | VAF 580/864 reads (67%) | SIFT tolerated (0.09); PolyPhen benign (0.034); called by mutect2, varscan2
- TRIM42 | c.1579C>G p.L527V | Missense Mutation (SNP) | VAF 438/1137 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- TSPAN3 | c.697G>C p.V233L | Missense Mutation (SNP) | VAF 162/894 reads (18%) | SIFT tolerated (0.54); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- ZC3H3 | c.2182G>A p.V728M | Missense Mutation (SNP) | VAF 480/1445 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- NKD1 | c.495G>A p.E165= | Silent (SNP) | VAF 455/982 reads (46%) | catalogued as COSV99194109; called by muse, mutect2, varscan2
- OR5H14 | c.804T>C p.D268= | Silent (SNP) | VAF 580/1150 reads (50%) | catalogued as rs1313700873; called by muse, mutect2, varscan2
- REXO4 | c.294G>A p.K98= | Silent (SNP) | VAF 301/1331 reads (23%) | called by muse, mutect2, varscan2
- CXorf56 | c.382-67A>C | Intron (SNP) | VAF 79/154 reads (51%) | called by muse, mutect2, varscan2
- CYLD | c.2686+46T>C | Intron (SNP) | VAF 164/368 reads (45%) | called by muse, mutect2, varscan2
- LCP2 | c.-86C>T | 5'UTR (SNP) | VAF 35/108 reads (32%) | catalogued as rs1199982688; called by muse, mutect2, varscan2
- NLGN1 | c.*48A>T | 3'UTR (SNP) | VAF 164/1494 reads (11%) | catalogued as rs1321169387; called by mutect2, varscan2
- RPL7 | c.-13dup | 5'UTR (INS) | VAF 1957/4079 reads (48%) | catalogued as rs774791493; called by mutect2, pindel, varscan2
